Somatic mutation profile of tumor specimen TCGA-HI-7170-01A (aliquot TCGA-HI-7170-01A-11D-2114-08) from TCGA case TCGA-HI-7170, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.0 years (21,199 days).
Specimen TCGA-HI-7170-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79bddcd8-64ab-4772-b236-ce864e2adc17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HI-7170-10A (Blood Derived Normal), aliquot TCGA-HI-7170-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60d6d88f-16b4-4275-b669-5e14de44f6ac

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Frame Shift Ins 2, Nonsense Mutation 1, Frame Shift Del 1, Intron 1, 3'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3034_3036del p.K1012del | In Frame Del (DEL) | VAF 20/103 reads (19%) | hotspot (GDC flag); catalogued as rs761762028; called by pindel, varscan2
- ADAM12 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV64112883; called by muse, mutect2, varscan2
- CENPB | c.242T>A p.L81H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60149142; called by muse, mutect2, varscan2
- COL7A1 | c.3820C>A p.P1274T | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.903); catalogued as COSV60401595; called by muse, mutect2, varscan2
- DNAJC16 | c.1644C>G p.F548L | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV65449298; called by muse, mutect2, varscan2
- EPHB3 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as rs34170386, COSV57808574; called by muse, mutect2, varscan2
- HELQ | c.1273A>G p.T425A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as COSV55027135; called by muse, mutect2, varscan2
- IGKV1D-13 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs376818855; called by muse, mutect2, varscan2
- MERTK | c.515C>A p.S172* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV54934444; called by muse, mutect2, varscan2
- NUP210 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV54412232; called by muse, mutect2, varscan2
- PRKAG1 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60294324; called by muse, mutect2, varscan2
- SPATA18 | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV54649041; called by muse, mutect2
- TAS2R5 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332092827, COSV56095479; called by muse, mutect2, varscan2
- UGT2B11 | c.1399G>T p.V467F | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774662170, COSV71424160; called by muse, mutect2, varscan2
- WDR17 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV54569151; called by muse, mutect2, varscan2
- ZRSR2 | c.121+1G>T p.X41_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57066906; called by muse, mutect2, varscan2
- KMT2D | c.5445_5446insT p.E1816* | Frame Shift Ins (INS) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- RBM10 | c.1716_1722dup p.D575Pfs*4 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, varscan2
- SENP5 | c.1003_1021del p.G335Tfs*31 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP44 | c.747G>A p.E249= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV52389074; called by muse, mutect2
- EN2 | c.771G>A p.Q257= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV52083847; called by muse, mutect2, varscan2
- GALNT10 | c.966C>T p.F322= | Silent (SNP) | VAF 48/217 reads (22%) | catalogued as rs757615516, COSV51720757; called by muse, mutect2, varscan2
- TENM3 | c.4413C>T p.L1471= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV69316421; called by muse, mutect2, varscan2
- CEP295 | chr11:93732115 C>T | 3'Flank (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- PLCE1 | c.1207-42859A>T | Intron (SNP) | VAF 6/96 reads (6%) | catalogued as COSV53367078; called by muse, mutect2
